Somatic mutation profile of tumor specimen TCGA-DJ-A2Q6-01A (aliquot TCGA-DJ-A2Q6-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2Q6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.9 years (14,193 days).
Specimen TCGA-DJ-A2Q6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1feaf21d-8259-4c70-bcb7-7e3fb0887ea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q6-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q6-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5fece08-bc4d-49ca-a7fe-a6a7013b50e5

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP2C9 | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs139656048; called by muse, mutect2
- OR4D5 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs143337717; called by muse, mutect2, varscan2
- ZNF804A | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as rs1300852164, COSV56433664; called by muse, mutect2, varscan2
- ST18 | c.1862dup p.N621Kfs*14 | Frame Shift Ins (INS) | VAF 18/86 reads (21%) | called by mutect2, varscan2
